Somatic mutation profile of tumor specimen 0DSPLU from CCDI case PBCHLS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,770 days).
Specimen 0DSPLU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1153b550-d320-4be9-9a5c-9ae352aa3e6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSPLZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d24e3e0d-fe12-4b87-b1ef-439719ef7548

The open-access MAF lists 74 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Intron 9, 3'UTR 3, 5'UTR 3, RNA 2, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 197/573 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- PURA | c.812_814del p.F271del | In Frame Del (DEL) | VAF 223/521 reads (43%) | catalogued as rs587782991; ClinVar: pathogenic; called by mutect2, varscan2
- ACSM2B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 323/745 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367698409; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 292/698 reads (42%) | catalogued as rs1295739623; called by muse, mutect2, varscan2
- ALDOA | c.598G>A p.A200T (on ENST00000642816 / NM_001243177.4; = p.A146T on NM_184041.5) | Missense Mutation (SNP) | VAF 301/606 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs1439374477, COSV57633197; called by muse, varscan2
- ARPP21 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 48/890 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs1054166241; called by muse, mutect2
- BPIFB3 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 224/464 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs199722228, COSV64956789; called by muse, mutect2, varscan2
- CFAP54 | c.5496G>T p.K1832N | Missense Mutation (SNP) | VAF 63/642 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.422); catalogued as COSV61571308; called by muse, mutect2, varscan2
- COL19A1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 344/1013 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416918271, COSV59588444; called by muse, mutect2, varscan2
- DCHS2 | c.1466T>A p.F489Y | Missense Mutation (SNP) | VAF 199/428 reads (46%) | SIFT tolerated (0.91); PolyPhen benign (0.076); catalogued as rs1248497893; called by muse, mutect2, varscan2
- DRC7 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 222/651 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375048759; called by muse, mutect2, varscan2
- ERBB3 | c.3406C>T p.R1136C | Missense Mutation (SNP) | VAF 147/367 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs79759315; called by muse, mutect2, varscan2
- EYA2 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 61/673 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs769484018, COSV100427095; called by muse, mutect2
- GSC | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 33/595 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450436; called by muse, mutect2
- HTR3A | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 158/384 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100248237; called by muse, mutect2, varscan2
- INPP5J | c.2224C>T p.R742W (on ENST00000331075 / NM_001284285.2; = p.R374W on NM_001002837.2) | Missense Mutation (SNP) | VAF 121/293 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1376875611, COSV53210733; called by muse, mutect2, varscan2
- MLF2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 37/719 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs986924880; called by muse, mutect2
- OR8B2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 65/1206 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs539279398; called by muse, mutect2
- PCNX2 | c.2626G>A p.V876I | Missense Mutation (SNP) | VAF 341/788 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs553389216, COSV50782205; called by muse, mutect2, varscan2
- PDGFRA | c.869G>C p.C290S | Missense Mutation (SNP) | VAF 1968/2386 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57276228; called by muse, mutect2, varscan2
- PRKCB | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 54/567 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57778554; called by muse, mutect2
- PTCH1 | c.1397A>T p.Q466L | Missense Mutation (SNP) | VAF 37/954 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1514895, COSV59467406; called by muse, mutect2
- SCN11A | c.5108T>A p.M1703K | Missense Mutation (SNP) | VAF 283/741 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs377712618; called by muse, mutect2, varscan2
- SLC16A12 | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 269/626 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV100370335; called by mutect2, varscan2
- SYTL2 | c.2596G>C p.V866L (on ENST00000528231 / NM_001162951.2; = p.V842L on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/932 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1238894556, COSV60364417; called by muse, mutect2
- TKTL2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 206/558 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs905050983; called by muse, mutect2, varscan2
- TTN | c.93988C>T p.R31330C (on ENST00000591111; = p.R23906C on NM_003319.4) | Missense Mutation (SNP) | VAF 357/805 reads (44%) | PolyPhen probably damaging (0.998); catalogued as rs765870426, COSV100619583, COSV60241433; called by muse, mutect2, varscan2
- ZNF280C | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 52/782 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs778134912; called by muse, mutect2
- CAPZA2 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 380/905 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- COL4A2 | c.5096G>T p.R1699L | Missense Mutation (SNP) | VAF 135/549 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- DNAH8 | c.11470A>G p.M3824V | Missense Mutation (SNP) | VAF 34/762 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- HTT | c.6958G>T p.V2320L | Missense Mutation (SNP) | VAF 170/496 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LRRIQ1 | c.4440G>T p.W1480C | Missense Mutation (SNP) | VAF 215/725 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); called by mutect2, varscan2
- MMP27 | c.1430del p.I477Tfs*11 | Frame Shift Del (DEL) | VAF 358/969 reads (37%) | called by mutect2, varscan2
- NEXMIF | c.2543C>A p.T848N | Missense Mutation (SNP) | VAF 226/465 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PCDHA2 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 42/935 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PKHD1L1 | c.8722A>C p.N2908H | Missense Mutation (SNP) | VAF 288/698 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPTA1 | c.248A>T p.D83V | Missense Mutation (SNP) | VAF 182/943 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TEP1 | c.4921G>T p.A1641S | Missense Mutation (SNP) | VAF 35/727 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- TPD52 | c.602T>A p.V201D (on ENST00000379097 / NM_001025252.3; = p.V161D on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 282/640 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VCL | c.3072G>T p.K1024N (on ENST00000211998 / NM_014000.3; = p.K956N on NM_003373.4) | Missense Mutation (SNP) | VAF 348/791 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZNF723 | c.413C>A p.T138K | Missense Mutation (SNP) | VAF 69/574 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.327); called by mutect2, varscan2
- ZNF786 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 184/472 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ACTL9 | c.789C>T p.S263= | Silent (SNP) | VAF 134/334 reads (40%) | catalogued as rs781970744, COSV100185481; called by muse, mutect2
- CES3 | c.1203C>T p.D401= | Silent (SNP) | VAF 59/831 reads (7%) | catalogued as rs369988942, COSV57595350; called by muse, mutect2
- CFAP47 | c.3588T>A p.T1196= | Silent (SNP) | VAF 560/687 reads (82%) | called by muse, mutect2, varscan2
- CSK | c.1281C>T p.A427= | Silent (SNP) | VAF 87/446 reads (20%) | catalogued as rs1213034503; called by muse, mutect2, varscan2
- CYYR1 | c.354C>T p.H118= | Silent (SNP) | VAF 322/851 reads (38%) | catalogued as rs576432831, COSV54829051; called by muse, mutect2, varscan2
- DLK1 | c.1065C>T p.S355= | Silent (SNP) | VAF 71/307 reads (23%) | catalogued as rs377178293; called by muse, mutect2, varscan2
- FLT3 | c.1395G>A p.K465= | Silent (SNP) | VAF 109/415 reads (26%) | called by muse, mutect2, varscan2
- FSIP2 | c.7032G>A p.S2344= | Silent (SNP) | VAF 192/1244 reads (15%) | catalogued as rs578237893, COSV100554884; called by muse, mutect2, varscan2
- MYH6 | c.2865C>T p.D955= | Silent (SNP) | VAF 257/620 reads (41%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1671G>A p.S557= | Silent (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- PXDN | c.3270C>A p.P1090= | Silent (SNP) | VAF 157/462 reads (34%) | called by muse, mutect2, varscan2
- TIMD4 | c.321C>T p.S107= | Silent (SNP) | VAF 296/734 reads (40%) | catalogued as rs367759946; called by muse, mutect2, varscan2
- TPCN2 | c.1809C>T p.G603= | Silent (SNP) | VAF 172/472 reads (36%) | catalogued as rs202156575; called by muse, mutect2, varscan2
- UGT1A6 | c.1512C>T p.I504= | Silent (SNP) | VAF 52/884 reads (6%) | called by muse, mutect2
- C16orf78 | c.*28C>A | 3'UTR (SNP) | VAF 152/261 reads (58%) | called by mutect2, varscan2
- CNGB1 | c.2370-10C>T | Intron (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.*3811del | 3'UTR (DEL) | VAF 64/462 reads (14%) | catalogued as rs1009738174; called by mutect2, varscan2
- CSH2 | c.171+23C>T | Intron (SNP) | VAF 88/412 reads (21%) | catalogued as rs767071549; called by muse, mutect2, varscan2
- DENND1B | c.*62_*63del | 3'UTR (DEL) | VAF 58/144 reads (40%) | called by mutect2, varscan2
- DPEP1 | c.-66C>T | 5'UTR (SNP) | VAF 76/129 reads (59%) | catalogued as rs866213715, COSV55360295; called by mutect2, varscan2
- EARS2 | c.486-48C>T | Intron (SNP) | VAF 34/104 reads (33%) | called by muse, varscan2
- GMDS | c.-62G>C | 5'UTR (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- HES6 | c.82-15C>T | Intron (SNP) | VAF 95/212 reads (45%) | called by muse, mutect2, varscan2
- MCM3AP | c.5785-16T>A | Intron (SNP) | VAF 204/476 reads (43%) | called by muse, mutect2, varscan2
- MS4A6A | c.651+15C>T | Intron (SNP) | VAF 37/554 reads (7%) | catalogued as rs1225122544; called by muse, mutect2
- MST1L | n.539G>A | RNA (SNP) | VAF 108/1573 reads (7%) | catalogued as rs754115424; called by muse, varscan2
- PKD1L2 | n.437T>C | RNA (SNP) | VAF 20/651 reads (3%) | called by muse, mutect2
- POR | c.189-4314G>A | Intron (SNP) | VAF 10/19 reads (53%) | catalogued as rs11979171; called by muse, mutect2, varscan2
- SPP1 | c.-5C>G | 5'UTR (SNP) | VAF 207/659 reads (31%) | called by muse, mutect2, varscan2
- SVOPL | c.274-24G>A | Intron (SNP) | VAF 106/412 reads (26%) | catalogued as rs769601540, COSV55991014; called by muse, mutect2, varscan2
- TACC1 | c.162-61T>G | Intron (SNP) | VAF 133/260 reads (51%) | called by muse, mutect2, varscan2
